Somatic mutation profile of tumor specimen TCGA-CG-4441-01A (aliquot TCGA-CG-4441-01A-01D-1800-08) from TCGA case TCGA-CG-4441, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 83.6 years (30,528 days).
Specimen TCGA-CG-4441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f18b6b6-dda9-40b1-b0d2-e53e79af0035.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4441-10A (Blood Derived Normal), aliquot TCGA-CG-4441-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bff4d77e-c60d-4e8d-b912-8fa5045e721c

The open-access MAF lists 118 somatic variants for this specimen: 86 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 31, Nonsense Mutation 3, Frame Shift Ins 3, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SDHB | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138996609, CM034573, COSV64965126; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1025980496, COSV55113658, COSV55115540; called by muse, mutect2, varscan2
- ACAN | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV61359069; called by muse, mutect2, varscan2
- ACP7 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as rs781471966, COSV58698833; called by muse, mutect2, varscan2
- ADAMTS5 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs773798738, COSV53177239; called by muse, mutect2, varscan2
- AKAP13 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs759395748, COSV63453869; called by muse, mutect2, varscan2
- ARMCX6 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs1394578185, COSV62680669; called by muse, mutect2, varscan2
- ARPP21 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99493814; called by muse, mutect2
- ATP1A2 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399834873, COSV63403362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP4A | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52867261; called by muse, mutect2, varscan2
- BAHCC1 | c.7478G>A p.R2493Q | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs782768076, COSV57025265; called by muse, mutect2, varscan2
- BAZ2B | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV54275148; called by muse, mutect2, varscan2
- BRINP2 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV64176948; called by muse, mutect2, varscan2
- C8B | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs955479183, COSV100980703, COSV64777175; called by muse, mutect2
- CAMK2G | c.275+2T>C p.X92_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV59481212; called by muse, mutect2
- CASKIN2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs772690752, COSV58594884; called by muse, mutect2, varscan2
- CETN1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59121192; called by muse, mutect2, varscan2
- CFH | c.3629G>A p.R1210H | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs1460283484, COSV66407526; called by muse, mutect2, varscan2
- CNTN4 | c.463T>A p.Y155N | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61871391; called by muse, mutect2, varscan2
- COL5A1 | c.2792G>A p.G931D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65667890; called by muse, mutect2
- CTTNBP2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs745621558, COSV50395651; called by muse, mutect2, varscan2
- DAOA | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.02); catalogued as COSV61602154; called by muse, mutect2, varscan2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- DDX43 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); catalogued as COSV100946485, COSV64836729; called by muse, mutect2, varscan2
- DNAH5 | c.8791T>C p.F2931L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54218235; called by muse, mutect2, varscan2
- DSEL | c.3563A>C p.N1188T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.281); catalogued as COSV59490753; called by muse, mutect2, varscan2
- EFNB3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56833244; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs138781990; called by muse, mutect2, varscan2
- EP300 | c.5209C>T p.R1737C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54330803; called by muse, mutect2, varscan2
- ERICH3 | c.3906C>A p.C1302* | Nonsense Mutation (SNP) | VAF 7/194 reads (4%) | catalogued as COSV100445413, COSV58604434; called by muse, mutect2
- FAM184A | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs907958825, COSV58852042; called by muse, mutect2, varscan2
- FAT1 | c.13039C>T p.P4347S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs1292626851, COSV71673370; called by muse, mutect2, varscan2
- FSCN1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1212305702, COSV61017342; called by muse, mutect2, varscan2
- GRIK3 | c.124T>G p.F42V | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66138302; called by muse, mutect2, varscan2
- HDAC7 | c.1984G>A p.A662T (on ENST00000427332; = p.A701T on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50339164; called by muse, mutect2, varscan2
- HFM1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.081); catalogued as COSV54025631; called by muse, mutect2, varscan2
- HIF1AN | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762795856, COSV54499882; called by muse, mutect2, varscan2
- HPX | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs201159600, COSV56419030; called by muse, mutect2, varscan2
- ITGB4 | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52324586; called by muse, mutect2, varscan2
- JHY | c.1916G>T p.R639I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV57074377; called by muse, mutect2, varscan2
- KNL1 | c.2693T>C p.M898T (on ENST00000346991 / NM_170589.5; = p.M872T on NM_144508.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs372672562; called by mutect2, varscan2
- LZTS2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs762091213, COSV64651079, COSV64651396; called by muse, mutect2, varscan2
- MCM7 | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57995674; called by muse, mutect2, varscan2
- MED16 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs955202726, COSV54125382; called by muse, mutect2, varscan2
- MOV10L1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as rs532990542, COSV53169936; called by muse, mutect2, varscan2
- NAV3 | c.3047C>T p.T1016I | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57074258, COSV57092060; called by muse, mutect2, varscan2
- OR2F2 | c.902G>A p.W301* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV68832693; called by muse, mutect2, varscan2
- OR2L13 | c.418T>A p.C140S | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV63551727; called by muse, mutect2, varscan2
- OR4F15 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); catalogued as COSV59968755; called by muse, mutect2, varscan2
- OR51I1 | c.925T>G p.F309V | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs199606552, COSV100970179, COSV66507657; called by muse, mutect2, varscan2
- OR6N1 | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58647976; called by muse, mutect2, varscan2
- OR6T1 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.233); catalogued as COSV58306488, COSV58309678; called by muse, mutect2, varscan2
- OTOP3 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs749573710, COSV60912896; called by muse, mutect2, varscan2
- P4HA2 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51324488; called by muse, mutect2, varscan2
- PAPOLB | c.1252A>G p.N418D | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68200283; called by muse, mutect2, varscan2
- PCDHA1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.806); catalogued as rs1554117547, COSV65373726; called by muse, mutect2, varscan2
- PTPN13 | c.510A>C p.K170N | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57405728; called by muse, mutect2, varscan2
- PTPRT | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV61974715; called by muse, mutect2, varscan2
- RAB10 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53089241; called by muse, mutect2
- REXO4 | c.1112T>G p.I371S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV64241581; called by muse, mutect2, varscan2
- RGS12 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs149618433; called by muse, mutect2, varscan2
- RIDA | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV54704520; called by muse, mutect2
- RTL1 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs781425496, COSV66016588; called by muse, mutect2, varscan2
- SCN7A | c.1406A>C p.K469T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs917164746, COSV69270701; called by muse, mutect2
- SLC27A4 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs200769384; called by muse, mutect2, varscan2
- SMC3 | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV62419742; called by muse, mutect2, varscan2
- SPACA9 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201660249, COSV53765895; called by muse, mutect2
- TAS2R1 | c.212T>G p.F71C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV66778427; called by muse, mutect2, varscan2
- TCIRG1 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55835182; called by muse, mutect2, varscan2
- TLL1 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50272408; called by muse, mutect2, varscan2
- TMEM62 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs748241104, COSV53040771, COSV53042690; called by muse, mutect2, varscan2
- TNFRSF9 | c.747A>C p.E249D | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66349034; called by muse, mutect2, varscan2
- TP53TG5 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.633); catalogued as COSV54781635; called by muse, mutect2, varscan2
- TTLL3 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs35644696; called by muse, mutect2, varscan2
- TTN | c.17906T>G p.V5969G (on ENST00000591111; = p.V5042G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/139 reads (23%) | PolyPhen possibly damaging (0.731); catalogued as COSV59991908; called by muse, mutect2, varscan2
- TULP4 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV65574444; called by muse, mutect2, varscan2
- UNC79 | c.2306G>A p.R769H (on ENST00000393151 / NM_001346218.2; = p.R592H on NM_020818.5) | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs188822336, COSV56382958; called by muse, mutect2, varscan2
- UQCRQ | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV51526079; called by muse, mutect2, varscan2
- VAX2 | c.771T>A p.D257E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV52265632; called by muse, mutect2
- VPS26C | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV55705862; called by muse, mutect2, varscan2
- ZNF606 | c.2030A>G p.E677G | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV58705661; called by muse, mutect2, varscan2
- ZNF677 | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV61720040; called by muse, mutect2, varscan2
- LIFR | c.1702dup p.I568Nfs*12 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- PCDHGB7 | c.2056dup p.A686Gfs*2 | Frame Shift Ins (INS) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- POMGNT1 | c.318_323del p.R107_S108del | In Frame Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- RIOK3 | c.1221_1227dup p.Y410Qfs*2 | Frame Shift Ins (INS) | VAF 19/66 reads (29%) | called by mutect2, varscan2
- ABCC1 | c.3450G>A p.P1150= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs4148377; called by muse, mutect2, varscan2
- ACSS1 | c.1599C>T p.D533= | Silent (SNP) | VAF 45/184 reads (24%) | catalogued as rs1230055609, COSV60219305; called by muse, mutect2, varscan2
- APBB1 | c.2010C>G p.T670= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV54967560; called by muse, mutect2, varscan2
- ASB7 | c.528C>T p.I176= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs774743185, COSV58403600; called by muse, mutect2, varscan2
- BRD3 | c.1287G>A p.A429= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs768208572, COSV57701237; called by muse, mutect2, varscan2
- BSN | c.7722C>T p.P2574= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV56516069; called by muse, mutect2, varscan2
- BUD31 | c.243A>G p.E81= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV52862676; called by muse, mutect2
- DHCR24 | c.678C>T p.A226= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs772464402, COSV64874518; called by muse, mutect2, varscan2
- FMO2 | c.57G>A p.K19= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as rs764445127, COSV52947307; called by muse, mutect2
- FZR1 | c.1251G>T p.T417= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs375592684, COSV58051313; called by muse, mutect2, varscan2
- GNA12 | c.1005C>T p.F335= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs532433262, COSV51740135; called by muse, mutect2, varscan2
- HIVEP2 | c.5766C>T p.D1922= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs190688683, COSV50006811; called by muse, mutect2, varscan2
- MOS | c.744G>T p.P248= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV61336164, COSV61336874; called by muse, mutect2, varscan2
- MTF1 | c.276T>G p.G92= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV65960391; called by muse, mutect2, varscan2
- NALCN | c.3676T>C p.L1226= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV51929456; called by muse, mutect2, varscan2
- NCOR2 | c.5592C>T p.T1864= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV62296556; called by muse, mutect2, varscan2
- OR2T12 | c.909G>A p.L303= | Silent (SNP) | VAF 73/209 reads (35%) | catalogued as COSV58777151; called by muse, mutect2, varscan2
- OR5D18 | c.567T>G p.S189= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as rs777828616, COSV61736452, COSV61736816; called by muse, mutect2, varscan2
- PCDHB5 | c.2181C>T p.P727= | Silent (SNP) | VAF 72/216 reads (33%) | catalogued as COSV50649659; called by muse, mutect2, varscan2
- PTK6 | c.507C>T p.P169= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV53916504; called by muse, mutect2
- PXYLP1 | c.1125C>T p.Y375= | Silent (SNP) | VAF 62/182 reads (34%) | catalogued as COSV53889975; called by muse, mutect2, varscan2
- SACS | c.5067T>C p.S1689= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV66537063; called by muse, mutect2, varscan2
- SLC17A6 | c.45G>C p.G15= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV54135364; called by muse, mutect2, varscan2
- SLC24A4 | c.519C>T p.I173= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs768955114, COSV54106994; called by muse, mutect2, varscan2
- SLC38A10 | c.3018C>T p.D1006= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs759843202; called by muse, mutect2, varscan2
- SPATA46 | c.582C>T p.T194= | Silent (SNP) | VAF 59/202 reads (29%) | catalogued as rs569380495, COSV62633949; called by muse, mutect2, varscan2
- THAP4 | c.387G>A p.P129= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV67191229; called by muse, mutect2, varscan2
- TMEM132D | c.1800A>C p.S600= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV67159847; called by muse, mutect2, varscan2
- TRPM2 | c.3003C>T p.T1001= | Silent (SNP) | VAF 27/232 reads (12%) | catalogued as rs768276564, COSV55966016, COSV55968937; called by muse, mutect2, varscan2
- ZMAT1 | c.1236T>G p.T412= | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as COSV65658231; called by muse, mutect2, varscan2
- ZNF562 | c.666C>T p.H222= (on ENST00000453372 / NM_001130032.2; = p.H150= on NM_017656.4) | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1273844446, COSV53333428; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85675C>T | Intron (SNP) | VAF 38/163 reads (23%) | catalogued as COSV72275493; called by muse, mutect2, varscan2
